Somatic mutation profile of tumor specimen MMRF_1195_1_BM_CD138pos (aliquot MMRF_1195_1_BM_CD138pos_T2_TSE61_K03425) from MMRF case MMRF_1195, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.7 years (22,172 days).
Specimen MMRF_1195_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60b8569f-fc37-48ba-9199-35c54601f747.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1195_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1195_1_PB_Whole_C1_TSE61_K03426; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0cbae87c-31ad-4144-ab77-5c8035404e13

The open-access MAF lists 107 somatic variants for this specimen: 54 protein-altering or splice-affecting, 15 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, 3'UTR 26, Silent 15, Nonsense Mutation 4, 5'UTR 3, 5'Flank 3, Intron 3, 3'Flank 2, Frame Shift Del 2, Frame Shift Ins 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 14/33 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- OAT | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs121965047, CM880055; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ARMC4 | c.2650G>T p.E884* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as COSV59470509; called by muse, mutect2, varscan2
- ASCC1 | c.319G>A p.D107N (on ENST00000342444 / NM_001369085.1; = p.D79N on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.079); catalogued as rs780444781; called by muse, mutect2, varscan2
- CAMKMT | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.564); catalogued as COSV101035499; called by muse, mutect2, varscan2
- CCDC105 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.075); catalogued as rs918023086; called by muse, mutect2, varscan2
- CDH11 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs957826065, COSV51770412; called by muse, mutect2, varscan2
- DNAH9 | c.9703G>A p.E3235K | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.903); catalogued as rs758714481; called by muse, mutect2, varscan2
- DPY19L3 | c.1829C>T p.A610V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.234); catalogued as rs778691909, COSV60480571; called by muse, mutect2, varscan2
- H1-8 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.541); catalogued as rs777818723; called by muse, mutect2, varscan2
- HECW2 | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs984877524, COSV53671804, COSV53676260; called by muse, mutect2, varscan2
- INAVA | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 55/84 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs367914105; called by muse, mutect2, varscan2
- KRTAP1-3 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 115/242 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757202386; called by muse, mutect2, varscan2
- LAMA3 | c.986C>T p.T329M | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs373289004; called by muse, mutect2, varscan2
- LAMC3 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 79/237 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as rs372107086, COSV100735914; called by muse, mutect2, varscan2
- MAFB | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64827074; called by muse, mutect2, varscan2
- MMP17 | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs750453920, COSV62179671; called by muse, mutect2, varscan2
- MXRA5 | c.7240G>T p.G2414C | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1188299436; called by muse, mutect2, varscan2
- NOP58 | c.1249_1250del p.E417Kfs*3 | Frame Shift Del (DEL) | VAF 17/43 reads (40%) | catalogued as rs768783326; called by mutect2, pindel, varscan2
- NYAP2 | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs377307715; called by muse, mutect2, varscan2
- OR4C3 | c.634C>A p.L212M | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1363629237; called by muse, mutect2, varscan2
- PCDHB4 | c.2168G>A p.R723H | Missense Mutation (SNP) | VAF 258/907 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.582); catalogued as COSV52026068; called by muse, mutect2, varscan2
- POLR2B | c.3053A>G p.Y1018C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.989); catalogued as rs1420625581, COSV58902174; called by muse, mutect2, varscan2
- PRG4 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.082); catalogued as rs142813803; called by muse, mutect2, varscan2
- RFTN1 | c.825G>A p.G275= | Splice Region (SNP) | VAF 37/64 reads (58%) | catalogued as COSV61921891, COSV61924426; called by muse, mutect2
- RYR1 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs377558801; called by muse, mutect2, varscan2
- SIGLECL1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1222802505, COSV57061964; called by muse, mutect2, varscan2
- SULT2A1 | c.598C>G p.Q200E | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as COSV55764085; called by muse, mutect2, varscan2
- THSD7B | c.3922C>T p.L1308F (on ENST00000272643; = p.L1306F on NM_001316349.2) | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.599); catalogued as COSV99751434; called by muse, mutect2, varscan2
- TPTE | c.1165_1167del p.S389del (on ENST00000618007 / NM_199261.4; = p.S371del on NM_199259.4) | In Frame Del (DEL) | VAF 34/158 reads (22%) | catalogued as rs1427778942; called by mutect2, pindel, varscan2
- ZNF518A | c.3914C>G p.P1305R | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV60151489; called by muse, mutect2, varscan2
- APH1B | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- BCL7A | c.83T>A p.V28E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, varscan2
- HAUS3 | c.966G>A p.M322I | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSPG2 | c.10426C>T p.Q3476* | Nonsense Mutation (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- LAMA3 | c.2505del p.F835Lfs*65 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | called by mutect2, pindel, varscan2
- LDB3 | c.1079G>A p.S360N | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP1B | c.13192T>A p.C4398S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MTMR2 | c.1819C>A p.L607I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- OR56A3 | c.556A>G p.M186V | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PCNX1 | c.3058G>T p.G1020* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- PCNX1 | c.3059G>T p.G1020V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PFKL | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHLDB3 | c.1153T>C p.S385P | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- POT1 | c.338C>G p.P113R | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- QRICH2 | c.1951G>T p.V651F | Missense Mutation (SNP) | VAF 234/445 reads (53%) | SIFT tolerated (0.66); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- SEC14L5 | c.543G>C p.W181C | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SMURF2 | c.488G>A p.W163* | Nonsense Mutation (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- TENT5C | c.355_356dup p.L120Sfs*6 | Frame Shift Ins (INS) | VAF 55/150 reads (37%) | called by mutect2, pindel, varscan2
- TERB1 | c.1184G>C p.S395T | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.01); called by muse, mutect2
- TLX2 | c.349A>G p.T117A | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- TMEM131 | c.182A>G p.K61R | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, varscan2
- TRIM47 | c.1082A>T p.K361I | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRMT13 | c.26A>G p.H9R | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMZ1 | c.459C>T p.L153= | Silent (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- CA1 | c.255C>T p.F85= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV99809983; called by muse, mutect2, varscan2
- CHD3 | c.126G>A p.P42= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as rs772231915; called by muse, mutect2, varscan2
- CSMD1 | c.5361C>T p.N1787= (on ENST00000520002; = p.N1786= on NM_033225.6) | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs34443453; called by muse, mutect2, varscan2
- ERBB4 | c.1326C>A p.I442= | Silent (SNP) | VAF 18/24 reads (75%) | called by muse, mutect2, varscan2
- JAK3 | c.2133C>T p.F711= | Silent (SNP) | VAF 19/168 reads (11%) | catalogued as rs200726812; called by muse, mutect2, varscan2
- LMAN1L | c.1356C>T p.G452= | Silent (SNP) | VAF 26/110 reads (24%) | called by muse, mutect2, varscan2
- MED16 | c.390C>T p.P130= | Silent (SNP) | VAF 54/223 reads (24%) | catalogued as rs747151607; called by muse, varscan2
- MUC4 | c.4170C>T p.T1390= | Silent (SNP) | VAF 6/236 reads (3%) | catalogued as rs1236687296; called by muse, mutect2
- MYO15A | c.6918C>T p.G2306= | Silent (SNP) | VAF 53/98 reads (54%) | called by muse, mutect2, varscan2
- SP140 | c.1431G>C p.A477= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV59452439; called by muse, mutect2, varscan2
- STX2 | c.810G>T p.V270= | Silent (SNP) | VAF 27/48 reads (56%) | called by muse, mutect2, varscan2
- TMC8 | c.573G>T p.V191= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as COSV59211373; called by muse, mutect2
- TNXB | c.1680C>A p.P560= | Silent (SNP) | VAF 11/193 reads (6%) | called by muse, mutect2
- ZNF836 | c.1899T>C p.T633= | Silent (SNP) | VAF 275/579 reads (47%) | catalogued as rs759288271; called by muse, mutect2, varscan2
- ABCA13 | c.*1664T>C | 3'UTR (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- AC139769.1 | n.214-3893A>T | Intron (SNP) | VAF 128/629 reads (20%) | called by muse, mutect2, varscan2
- ADGRF3 | chr2:26309564 G>A | 3'Flank (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2
- AP000944.2 | chr11:65423060 del G | 5'Flank (DEL) | VAF 59/123 reads (48%) | called by mutect2, pindel, varscan2
- BCL6B | c.*377T>G | 3'UTR (SNP) | VAF 24/48 reads (50%) | called by muse, mutect2, varscan2
- CACNA1I | c.*3060T>C | 3'UTR (SNP) | VAF 34/67 reads (51%) | called by muse, mutect2, varscan2
- CACNA2D4 | c.*266del | 3'UTR (DEL) | VAF 17/54 reads (31%) | called by mutect2, pindel, varscan2
- CHORDC1 | c.*637A>C | 3'UTR (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
- ERICH3 | c.-86C>G | 5'UTR (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- FAXC | c.*3771C>A | 3'UTR (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- GABBR2 | c.*2105G>A | 3'UTR (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- GABRA2 | chr4:46389980 C>T | 5'Flank (SNP) | VAF 10/22 reads (45%) | called by muse, varscan2
- GFOD2 | c.259+2236C>A | Intron (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- GIGYF2 | c.*606T>C | 3'UTR (SNP) | VAF 18/66 reads (27%) | called by muse, mutect2, varscan2
- H2AC13 | c.*20G>A | 3'UTR (SNP) | VAF 129/237 reads (54%) | called by muse, mutect2, varscan2
- HOOK2 | c.*134T>G | 3'UTR (SNP) | VAF 35/160 reads (22%) | called by muse, mutect2, varscan2
- IARS2 | c.*205T>C | 3'UTR (SNP) | VAF 10/20 reads (50%) | catalogued as rs1253059074; called by muse, mutect2, varscan2
- KCNH1 | c.*1676C>T | 3'UTR (SNP) | VAF 35/89 reads (39%) | called by muse, mutect2, varscan2
- KLF16 | c.*156C>T | 3'UTR (SNP) | VAF 16/93 reads (17%) | catalogued as rs1315103478; called by muse, mutect2, varscan2
- KLK15 | chr19:50825686 T>A | 3'Flank (SNP) | VAF 25/113 reads (22%) | called by muse, mutect2, varscan2
- KNSTRN | c.*470C>T | 3'UTR (SNP) | VAF 34/125 reads (27%) | called by muse, mutect2, varscan2
- LINC00520 | n.484A>G | RNA (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2, varscan2
- LONRF2 | c.*2637del | 3'UTR (DEL) | VAF 19/70 reads (27%) | called by mutect2, pindel, varscan2
- MEI1 | chr22:41697524 A>C | 5'Flank (SNP) | VAF 25/58 reads (43%) | called by muse, mutect2, varscan2
- MPPED2 | c.*2021T>C | 3'UTR (SNP) | VAF 4/8 reads (50%) | catalogued as rs531519470; called by muse, varscan2
- MYO10 | c.*3343A>C | 3'UTR (SNP) | VAF 8/52 reads (15%) | called by muse, varscan2
- MYO1E | c.-69A>G | 5'UTR (SNP) | VAF 102/171 reads (60%) | called by muse, mutect2, varscan2
- NLE1 | c.*842C>T | 3'UTR (SNP) | VAF 35/90 reads (39%) | catalogued as rs1380723337; called by muse, mutect2, varscan2
- PPP2R2B | c.*95T>C | 3'UTR (SNP) | VAF 32/93 reads (34%) | catalogued as COSV60764310; called by muse, mutect2, varscan2
- RGMA | c.15-600G>A | Intron (SNP) | VAF 11/175 reads (6%) | called by muse, mutect2
- ROR2 | c.-169G>A | 5'UTR (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2
- RTN4 | c.*373T>C | 3'UTR (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- SEMA3C | c.*1064T>G | 3'UTR (SNP) | VAF 7/134 reads (5%) | called by muse, mutect2
- SLC30A3 | c.*394T>C | 3'UTR (SNP) | VAF 23/137 reads (17%) | called by muse, mutect2, varscan2
- STARD8 | c.*1010G>A | 3'UTR (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- STK10 | c.*1458G>A | 3'UTR (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- TLCD2 | c.*3530T>C | 3'UTR (SNP) | VAF 4/15 reads (27%) | catalogued as rs1425973123; called by muse, varscan2
- TSSK6 | c.*185C>T | 3'UTR (SNP) | VAF 15/108 reads (14%) | called by muse, mutect2, varscan2
